Surgical pathology report (de-identified scan), TCGA case TCGA-76-6656, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Thomas Jefferson University, specimen TCGA-76-6656-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

Patient: [REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED] TCGA - 76 - 6656

FINAL DIAGNOSIS:

1. Left parietal GBM: glioblastoma, grade IV of IV (WHO scale), see microscopic description, see note
2. Left parietall GBM: glioblastoma, grade IV of IV (WHO scale), see microscopic description, see note

Comment:

[REDACTED] reviewed selected slides and concurs with the presence of malignancy in this material.

[REDACTED]

Report Electronically Signed on [REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Microscopic Description:

The tumor consists of a moderately pleomorphic and infiltrative proliferation of astrocytes. There are numerous mitoses. There is abundant microvascular proliferation and extensive geographic necrosis. There are also small foci of pseudo-palisading necrosis. The findings are diagnostic of a glioblastoma, grade IV of IV (WHO scale).

Frozen Section Diagnosis:

- [REDACTED]
1. Left parietal GBM: Glioblastoma

[page 2 of 3]
[REDACTED]

Clinical History and Diagnosis:
Left parietal lesion

Source of Specimen:
1: Left parietal GBM
2: Left parietall GBM

Gross Description:

[REDACTED]

1. Left parietal GBM: Received fresh for frozen section in the specimen container labeled with patient name and "#1 left parietal GBM" is a 2.5 x 2 x 0.3 cm aggregate of tan-red soft tissue. Touch prep is done. 50% of the specimen is submitted for frozen section. The specimen is submitted as follows:

- A. FSC
- B. remainder of the specimen.

2. Left parietal GBM: Received in formalin, in a specimen container labeled with the patient's name and "#2 left parietal GBM", is a 0 x 3.0 x 2.0 cm aggregate of tan-pink soft, partially necrotic tissue. Representative sections are submitted in 5 cassettes(~ 70 % of the specimen).

Histology Laboratory
H&E

Immunohistochemistry Notes

1. Quantification of immunohistochemistry assay for ER and PR studies is by the method of Battiafora et.al. Applied Immunohistochemistry, [REDACTED]

2. Hercept Test (DakoCytomation) Formalin fixed, paraffin embedded.

[page 3 of 3]
[REDACTED]

Interpretation follows the manufacturer' s recommendation.

Documented by [REDACTED]
[REDACTED]

EGFR pharmDx Clone 2-18C9 Formalin fixed, paraffin embedded.
Interpretation follows the manufacturer' s recommendation.

Docuemented by [REDACTED]
[REDACTED]

3. Analyte Specific Reagent (ASCR) Disclaimer. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR).

These tests were developed and their performance characteristics determined by the [REDACTED]
[REDACTED]

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file b0e39c17-3b4d-4b89-956e-a87c11f453cb (TCGA-76-6656.916DA87B-E1F7-43FC-91B6-8DB07A5BA0B2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).